Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A81J, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A81J-01A (Primary Tumor).

Unique Patient Identifier:

Short descriptive translation of the pathology review reported by the

Pathoanatomical review

Date:

Date report:

Material: right adrenal

There is an adrenal tumor with a diameter of 2.5 cm.

Immunohistologically, there is positive staining for synaptophysin and chromogranin. Staining for Inhibin, SF1, Calretinin, MART1 and KL1 was negative. Only single cells stained positive for Ki67 pointing to a low rate of proliferation. A total score of 3 was found (Extension into adipose tissue, nuclear pleomorphism) indicating a benign disease.

Total Score Score (max. 20) 3

Final conclusion: pheochromocytoma

Translated by:

ICD-O-3
Pheochromocytoma NOS
8700/0
Site (R) Adrenal gland NOS
C74.9
9/10/17/13

Source: NCI Genomic Data Commons file 028105ac-ed63-4bfa-aed8-4191ec0b2d57 (TCGA-WB-A81J.5009A0BD-D759-4430-B1A1-C0C30F4E88C7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).